Gene-level copy-number profile of tumor specimen TCGA-BC-4073-01B from TCGA case TCGA-BC-4073, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 73.4 years (26,795 days).
Specimen TCGA-BC-4073-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.7c3b8331-8d0a-4285-881f-e4ce4747e151.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BC-4073-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0361d7ab-8dd2-4fa1-9c0f-0cb2dda4026c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 34; copy number 1: 6,225; copy number 2: 52,866; copy number 3: 688; copy number 5: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BC-4073-01B-02D-A12Y-01): tumor purity 0.55, ploidy 1.94, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 34 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:114,314,500–115,147,288, 1 gene (within-gene range 0–2): ZBTB20.
- chr3:114,351,771–114,743,525, 4 genes (within-gene range 0–2): ZBTB20-AS1, ZBTB20-AS5, ZBTB20-AS2, MIR4796.
- chr5:163,416,525–163,446,151, 2 genes: AC008723.1, CCNG1.
- chr7:69,594,793–70,793,506, 2 genes (within-gene range 0–2): CT66, AUTS2.
- chr9:109,375,466–109,498,313, 1 gene (within-gene range 0–2): PTPN3.
- chr9:109,511,475–109,534,332, 2 genes: MIR3927, YBX1P6.
- chr10:74,151,202–74,709,963, 7 genes (within-gene range 0–1): ADK, TIMM9P1, RPSAP6, RAB5CP1, AC022540.1, MRPL35P3, Y_RNA.
- chr10:75,431,624–76,560,168, 1 gene (within-gene range 0–1): LRMDA.
- chr10:76,242,022–76,438,775, 4 genes: RN7SL518P, RNU6-673P, AC012048.1, AC013286.1.
- chr10:126,988,095–127,026,507, 2 genes: AL359094.1, AL359094.2.
- chr11:83,643,602–83,815,263, 3 genes: DLG2-AS2, AP002370.1, LDHAL6DP.
- chr13:33,180,401–33,281,584, 1 gene: STARD13-AS.
- chr15:66,984,103–67,065,268, 1 gene (within-gene range 0–2): AC087482.1.
- chr15:67,063,763–67,195,169, 2 genes (within-gene range 0–2): SMAD3, AC012568.1.
- chr17:9,021,510–9,244,000, 1 gene (within-gene range 0–1): NTN1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:3,875,584–3,901,248, 2 genes, copy number 5: AL137071.1, GLIS3-AS1.

Autosomal genes at a single copy (total copy number 1): 3,805. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
